Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017978-09A.1 (aliquot TARGET-15-SJMPAL017978-09A.1-01D) from TARGET case TARGET-15-SJMPAL017978, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-15-SJMPAL017978-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3143be1-cfd8-4d4f-a743-01bd1a366ddc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017978-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL017978-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ebaf4f6-e14a-4136-ac50-46a5916f20a2

The open-access MAF lists 13 somatic variants for this specimen: 5 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 5, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM135B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200240655; called by muse, mutect2, varscan2
- FAM186A | c.4057A>C p.T1353P | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781639128, COSV59246156; called by muse, mutect2
- ANKFY1 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.386); called by muse, varscan2
- EXOC1 | c.2672C>A p.A891E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PPP1R21 | c.1915C>A p.P639T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.272); called by muse, mutect2
- BMP2 | c.906C>T p.Y302= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs374065751; called by muse, mutect2, varscan2
- GOLGA8O | c.507C>T p.R169= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs778644601; called by muse, mutect2, varscan2
- MARCHF10 | c.1221C>T p.S407= | Silent (SNP) | VAF 58/117 reads (50%) | catalogued as rs777152212; called by muse, mutect2, varscan2
- MROH2A | c.2355C>T p.C785= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs770274993; called by muse, mutect2, varscan2
- MUC4 | c.5550T>C p.S1850= | Silent (SNP) | VAF 43/484 reads (9%) | catalogued as rs749350452; called by muse, mutect2
- SSC5D | c.3858T>C p.T1286= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs763661185, COSV67476832; called by muse, mutect2
- HRC | c.*20C>T | 3'UTR (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2, varscan2
- NHSL1 | c.676+4907G>T | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
